Somatic mutation profile of tumor specimen be2d5946-3452-4003-880a-e0372e (aliquot be2d5946-3452-4003-880a-e0372e_D6_2) from CPTAC case 01CO014, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen be2d5946-3452-4003-880a-e0372e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 185d1e57-704d-4a55-81eb-0986eb9aa9da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 323ea2fc-46f2-4d43-9b5d-ca5164 (Blood Derived Normal), aliquot 323ea2fc-46f2-4d43-9b5d-ca5164_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/874e9dba-81f2-41f2-b4cb-3f176bbc0a63

The open-access MAF lists 1,467 somatic variants for this specimen: 968 protein-altering or splice-affecting, 299 silent, 200 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 662, Silent 299, Frame Shift Del 193, Intron 103, Nonsense Mutation 40, 3'UTR 30, Frame Shift Ins 26, RNA 26, Splice Site 25, 5'UTR 20, Splice Region 11, 3'Flank 11.

Variants (750 of 1,467; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 48/172 reads (28%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 68/318 reads (21%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 35/122 reads (29%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NPHP1 | c.555del p.K185Nfs*7 | Frame Shift Del (DEL) | VAF 34/112 reads (30%) | catalogued as rs766524637, CD1511891; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); catalogued as rs1257124719, COSV100909782, COSV64290925, COSV64293353; ClinVar: likely pathogenic; called by muse, varscan2
- RAD54L | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 168/606 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs121908688; ClinVar: pathogenic; called by mutect2, varscan2
- SLC19A3 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 93/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1131691615, CM157656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 125/476 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TPI1 | c.547G>T p.E183* (on ENST00000229270; = p.E146* on NM_000365.6) | Nonsense Mutation (SNP) | VAF 124/514 reads (24%) | catalogued as rs121964850, CM962415; ClinVar: pathogenic; called by mutect2, varscan2
- TRPS1 | c.2722C>T p.R908* (on ENST00000220888 / NM_001330599.2; = p.R921* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 143/558 reads (26%) | catalogued as rs751565386, CM154764, COSV55227212; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs772486562, COSV55540999; called by muse, mutect2, varscan2
- AC231657.3 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV59875890; called by muse, mutect2, varscan2
- ACP4 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 80/390 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.825); catalogued as rs746509593; called by muse, mutect2, varscan2
- ACSF3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 89/387 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs369499144, COSV58082397; called by muse, mutect2, varscan2
- ACSL6 | c.1638G>A p.P546= (on ENST00000379240; = p.P571= on NM_015256.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 46/207 reads (22%) | catalogued as rs368747747, COSV57295930; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADA2 | c.872C>T p.S291L (on ENST00000262607; = p.S50L on NM_177405.3) | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1390146619, COSV52833893; called by muse, mutect2, varscan2
- ADAMTS4 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as rs377253620; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 57/216 reads (26%) | catalogued as COSV65879385; called by mutect2, pindel, varscan2
- ADGRA1 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66931372; called by muse, mutect2, varscan2
- ADSS1 | c.197del p.X66_splice | Splice Site (DEL) | VAF 35/197 reads (18%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- AGO3 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs868117174; called by muse, mutect2, varscan2
- AKAP10 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs371370941, COSV56730732; called by muse, mutect2, varscan2
- ALPG | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs372434742; called by muse, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 18/191 reads (9%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- ANO1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as rs553969695; called by muse, mutect2, varscan2
- ANO3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760680753, COSV56807795, COSV99882662; called by muse, mutect2, varscan2
- ANXA2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs771090624, COSV100221830; called by muse, mutect2, varscan2
- APBB1 | c.849del p.G284Afs*48 | Frame Shift Del (DEL) | VAF 49/207 reads (24%) | catalogued as COSV54976931; called by mutect2, pindel, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs546686089; called by mutect2, varscan2
- APOH | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.419); catalogued as rs762150092; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs749401724; called by mutect2, varscan2
- ARAP1 | c.785G>A p.R262H (on ENST00000393609 / NM_001040118.2; = p.R17H on NM_015242.4) | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs748074025, COSV61992054; called by muse, mutect2, varscan2
- ARFGAP2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs369782750; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 76/327 reads (23%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGEF33 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.084); catalogued as rs1458496751; called by muse, mutect2, varscan2
- ARMH2 | c.136del p.I46Sfs*20 | Frame Shift Del (DEL) | VAF 52/172 reads (30%) | catalogued as rs965020534; called by mutect2, varscan2
- ATF4 | c.406del p.Q136Rfs*3 | Frame Shift Del (DEL) | VAF 46/145 reads (32%) | catalogued as rs770192882; called by mutect2, pindel, varscan2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP13A2 | c.3283C>A p.L1095I | Missense Mutation (SNP) | VAF 112/509 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.412); catalogued as COSV58703194; called by muse, mutect2, varscan2
- ATP6V0D1 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769147649, COSV52097279; called by muse, mutect2, varscan2
- ATRN | c.3976C>T p.R1326C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1031314497, COSV53524187; called by muse, mutect2, varscan2
- AVPR1B | c.604T>C p.W202R | Missense Mutation (SNP) | VAF 90/500 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781883502; called by muse, mutect2, varscan2
- B3GNT9 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1377383904, COSV54629136; called by muse, mutect2
- B4GALNT3 | c.1781T>C p.V594A | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV56751593; called by muse, mutect2
- BAZ2B | c.3983del p.K1328Rfs*27 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs762040174; called by mutect2, pindel, varscan2
- BIK | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.917); catalogued as rs11574527; called by muse, varscan2
- BOC | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 119/498 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs934615287; called by muse, mutect2, varscan2
- BORCS7 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs761568723; called by muse, mutect2, varscan2
- BRF1 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs750860515; called by muse, mutect2, varscan2
- BSG | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.102); catalogued as rs776735964; called by muse, mutect2, varscan2
- BTBD7 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs1186469824; called by muse, varscan2
- BTN2A1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 65/266 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778785394, COSV57001979; called by muse, mutect2, varscan2
- C11orf68 | c.730C>T p.R244C (on ENST00000530188; = p.R285C on NM_031450.4) | Missense Mutation (SNP) | VAF 57/236 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1001663632; called by muse, mutect2, varscan2
- C3 | c.4643G>A p.R1548Q | Missense Mutation (SNP) | VAF 117/522 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs778590435; called by muse, mutect2, varscan2
- CACNA1D | c.28del p.M10Cfs*60 | Frame Shift Del (DEL) | VAF 83/346 reads (24%) | catalogued as COSV55457798; called by mutect2, pindel, varscan2
- CACNA1I | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334625806, COSV100361280; called by muse, mutect2, varscan2
- CCDC154 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750513094; called by muse, mutect2, varscan2
- CCDC174 | c.908del p.K303Rfs*2 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | catalogued as rs1229700711; called by mutect2, pindel, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 62/246 reads (25%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDKN1A | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 115/441 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.863); catalogued as COSV55191500; called by muse, mutect2, varscan2
- CDR2L | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.966); catalogued as rs1420451259; called by muse, mutect2, varscan2
- CEP131 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs367933757; called by muse, mutect2, varscan2
- CEP192 | c.2362del p.T788Qfs*40 | Frame Shift Del (DEL) | VAF 44/210 reads (21%) | catalogued as COSV58068098; called by mutect2, pindel, varscan2
- CERS5 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1463335428, COSV58189254; called by muse, mutect2, varscan2
- CES1 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 86/569 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100828855; called by muse, mutect2, varscan2
- CFAP65 | c.3145C>T p.R1049* | Nonsense Mutation (SNP) | VAF 27/105 reads (26%) | catalogued as rs766962191, COSV100445636; called by muse, mutect2, varscan2
- CFP | c.1182dup p.C395Lfs*4 | Frame Shift Ins (INS) | VAF 80/428 reads (19%) | catalogued as rs1263452869; called by mutect2, pindel, varscan2
- CGNL1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs149230436; called by muse, mutect2, varscan2
- CHD6 | c.4177G>A p.A1393T | Missense Mutation (SNP) | VAF 55/227 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs147954398; called by muse, mutect2, varscan2
- CHD8 | c.3790G>A p.E1264K (on ENST00000646647 / NM_001170629.2; = p.E985K on NM_020920.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1389713229, COSV67869679; called by muse, mutect2, varscan2
- CHSY1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 109/392 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as rs573785211, COSV54253371; called by muse, mutect2, varscan2
- CLEC12A | c.223dup p.M75Nfs*9 | Frame Shift Ins (INS) | VAF 18/124 reads (15%) | catalogued as rs756570750; called by mutect2, varscan2
- CLN3 | c.308G>A p.R103Q (on ENST00000360019 / NM_001286104.2; = p.R127Q on NM_000086.2) | Missense Mutation (SNP) | VAF 86/360 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs780776829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | catalogued as rs369752219; called by mutect2, varscan2
- CMYA5 | c.5468del p.K1823Rfs*17 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs954878355; called by mutect2, pindel, varscan2
- CNGA3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs149230055; called by muse, mutect2, varscan2
- CNNM4 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 113/387 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs1558976548; called by muse, mutect2, varscan2
- CNR1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs771076412, COSV100759152; called by muse, mutect2, varscan2
- CNTROB | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs748617832; called by muse, mutect2, varscan2
- COL1A1 | c.441del p.G148Dfs*117 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | catalogued as rs1473458290, CD123304, CX1514539; called by mutect2, varscan2
- COL1A2 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759251034, COSV51963558; called by muse, mutect2, varscan2
- COL5A1 | c.1757del p.G586Efs*218 | Frame Shift Del (DEL) | VAF 38/215 reads (18%) | catalogued as COSV65665075, COSV65672413; called by mutect2, pindel, varscan2
- COL6A6 | c.866A>G p.K289R | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV100649947; called by muse, mutect2, varscan2
- COL9A3 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 105/390 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs778300099, COSV59655552; called by muse, mutect2, varscan2
- COLEC12 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 70/254 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs765394463, COSV68374660; called by muse, mutect2, varscan2
- COQ6 | c.1003G>A p.V335I | Missense Mutation (SNP) | VAF 240/946 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs147444011, COSV99473999; called by muse, varscan2
- CRACD | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 102/382 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1363465889, COSV51731746; called by muse, mutect2, varscan2
- CRAMP1 | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs553081131; called by muse, varscan2
- CRH | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs751705433; called by muse, mutect2, varscan2
- CRIM1 | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs923879556; called by muse, mutect2, varscan2
- CRY2 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 114/536 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs769872273, COSV101314554, COSV69889260; called by muse, mutect2, varscan2
- CSMD2 | c.10360C>T p.R3454W | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs144356782, COSV53914070, COSV53934576; called by muse, mutect2, varscan2
- CYB5D2 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs368344135; called by muse, mutect2, varscan2
- CYP27C1 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs560900927, COSV58866579; called by muse, mutect2, varscan2
- CYP2A6 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs58720852; called by muse, mutect2, varscan2
- CYP2A7 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs200248426, COSV52496852; called by muse, mutect2
- CYTH3 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs142012512; called by muse, mutect2, varscan2
- DAB2IP | c.3073del p.H1025Tfs*5 (on ENST00000408936; = p.H997Tfs*5 on NM_032552.3) | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | catalogued as rs751187768; called by mutect2, varscan2
- DCAF12L2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770854200, COSV63580452, COSV63582250; called by muse, mutect2, varscan2
- DCTN1 | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 147/581 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs766338463; called by muse, mutect2, varscan2
- DDC | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.058); catalogued as rs1459033416, COSV100779066, COSV63565602; called by muse, mutect2, varscan2
- DEFB104A | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.021); catalogued as rs763979054; called by mutect2, varscan2
- DFFB | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs776360511; called by muse, mutect2, varscan2
- DIDO1 | c.6005del p.N2002Mfs*17 | Frame Shift Del (DEL) | VAF 13/85 reads (15%) | catalogued as rs1568819830; called by mutect2, pindel, varscan2
- DIPK1A | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.787); catalogued as rs1421518354, COSV100942005; called by muse, mutect2, varscan2
- DLEC1 | c.145C>A p.L49I | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as COSV57302790; called by muse, mutect2, varscan2
- DLG4 | c.1173G>T p.Q391H (on ENST00000399506 / NM_001321075.3; = p.Q434H on NM_001365.4) | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV57237161; called by muse, mutect2
- DNAH5 | c.8821-1G>T p.X2941_splice | Splice Site (SNP) | VAF 66/303 reads (22%) | catalogued as rs1060501454, COSV54242372; called by muse, mutect2, varscan2
- DNAH9 | c.7361C>T p.T2454M | Missense Mutation (SNP) | VAF 101/409 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387545453, COSV52363465, COSV52377010; called by muse, mutect2, varscan2
- DNTTIP1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs779556936; called by muse, mutect2, varscan2
- DOK1 | c.35dup p.L12Ffs*33 | Frame Shift Ins (INS) | VAF 16/108 reads (15%) | catalogued as rs759252474; called by mutect2, varscan2
- DOK3 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs144901160; called by muse, mutect2, varscan2
- DPP6 | c.550del p.I184Lfs*4 (on ENST00000377770 / NM_001364500.2; = p.I122Lfs*4 on NM_001936.5) | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | catalogued as rs773847741; called by mutect2, pindel
- EFCAB6 | c.3623G>A p.R1208H | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs144440757; called by muse, mutect2, varscan2
- ELMO3 | c.1248del p.G417Vfs*44 (on ENST00000652269; = p.G364Vfs*44 on NM_024712.5) | Frame Shift Del (DEL) | VAF 54/230 reads (23%) | catalogued as rs781430251; called by mutect2, pindel, varscan2
- EMP1 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 64/524 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs370911293; called by muse, mutect2, varscan2
- ENO1 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 100/359 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.415); catalogued as rs1474027392; called by muse, mutect2, varscan2
- EPHA2 | c.2785G>A p.G929S | Missense Mutation (SNP) | VAF 58/248 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs765744442, COSV64453053, COSV64454563; called by muse, mutect2, varscan2
- ERICH1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1405472954; called by muse, mutect2, varscan2
- ERN1 | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148845267; called by muse, mutect2, varscan2
- ERVFRD-1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.337); catalogued as rs1283669010, COSV65369215; called by muse, mutect2, varscan2
- ESRRB | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV55062753; called by muse, mutect2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as COSV54136078; called by mutect2, pindel
- ETV6 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765947; called by muse, mutect2, varscan2
- F2 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 162/654 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs900863560, COSV100319641; called by muse, mutect2, varscan2
- FAM193A | c.2497del p.M833Wfs*23 | Frame Shift Del (DEL) | VAF 20/101 reads (20%) | catalogued as rs768952789; called by mutect2, pindel, varscan2
- FAM83H | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs781905219, COSV66354785; called by muse, mutect2, varscan2
- FAN1 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs145217832; called by muse, mutect2, varscan2
- FBXO21 | c.1603C>T p.R535W (on ENST00000330622 / NM_033624.3; = p.R528W on NM_015002.3) | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100401801; called by muse, mutect2, varscan2
- FBXO27 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as rs923431957; called by muse, mutect2, varscan2
- FBXO33 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs148776291; called by muse, mutect2, varscan2
- FDXR | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772347757, COSV53120117; called by muse, mutect2, varscan2
- FKBP8 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs371498399; called by muse, mutect2, varscan2
- FMO3 | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 119/255 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100882456; called by muse, mutect2, varscan2
- FOXO4 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs368209640, COSV99050878; called by muse, mutect2, varscan2
- FREM2 | c.6403C>T p.R2135* | Nonsense Mutation (SNP) | VAF 52/181 reads (29%) | catalogued as rs759639276; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs756304971; called by mutect2, varscan2
- GLCCI1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56202599; called by muse, mutect2, varscan2
- GLMN | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV64859787; called by muse, mutect2, varscan2
- GOLGA6L10 | c.1167G>T p.R389S | Missense Mutation (SNP) | VAF 124/583 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs774318020; called by muse, varscan2
- GOLM1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs745694988, COSV99974367; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 105/462 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, mutect2, varscan2
- GPRASP2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1327200158; called by muse, mutect2, varscan2
- GPT2 | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as rs762356280; called by muse, mutect2, varscan2
- GRIN2D | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1181465915; called by muse, mutect2, varscan2
- GRINA | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs560551768, COSV57297391; called by muse, mutect2
- GRM1 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as rs1429236981, COSV51370927; called by muse, mutect2, varscan2
- GZMA | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750590418, COSV57049469; called by muse, mutect2, varscan2
- H2BC12 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as rs746185453; called by muse, mutect2, varscan2
- H3C6 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as rs776406667, COSV64519844; called by muse, mutect2
- HAO1 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs576373242, COSV66493343; called by muse, mutect2, varscan2
- HDGFL2 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs369666897; called by muse, mutect2, varscan2
- HDLBP | c.3398C>T p.P1133L | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs368440496; called by muse, mutect2, varscan2
- HEPH | c.2716G>T p.G906C (on ENST00000343002; = p.G639C on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100293966; called by muse, mutect2, varscan2
- HHIPL1 | c.1300G>A p.G434S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1390452090; called by muse, mutect2, varscan2
- HIF3A | c.820G>A p.A274T (on ENST00000377670 / NM_152795.4; = p.A205T on NM_022462.4) | Missense Mutation (SNP) | VAF 64/232 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs753034506, COSV99355779; called by mutect2, varscan2
- HINT3 | c.201+1G>A p.X67_splice | Splice Site (SNP) | VAF 49/150 reads (33%) | catalogued as rs764144849; called by muse, mutect2, varscan2
- HIP1 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as rs781839337, COSV61185575; called by muse, mutect2
- HIVEP1 | c.1930G>T p.A644S | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65105142; called by muse, mutect2, varscan2
- HLA-A | c.627del p.K210Rfs*4 | Frame Shift Del (DEL) | VAF 39/223 reads (17%) | catalogued as rs199474609; called by mutect2, pindel, varscan2
- HLA-DPA1 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 99/428 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs1334072731; called by mutect2, varscan2
- HLX | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 97/490 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs752628182; called by muse, mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1556033122; called by mutect2, pindel, varscan2
- HNF1A | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 134/535 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.238); catalogued as rs371759652; called by muse, mutect2, varscan2
- HS6ST1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52128406; called by muse, mutect2
- HTR1F | c.918G>A p.W306* | Nonsense Mutation (SNP) | VAF 28/132 reads (21%) | catalogued as rs780856447; called by muse, mutect2, varscan2
- ICE1 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs538423183, COSV56824903; called by muse, mutect2, varscan2
- IER2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200894180; called by muse, mutect2, varscan2
- IFT140 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 69/253 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs754373519, COSV68490807; called by muse, mutect2, varscan2
- IGFN1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs897640928, COSV99811288; called by muse, mutect2
- IGLV3-1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 150/558 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs773986506; called by muse, mutect2, varscan2
- IGSF8 | c.479dup p.G161Rfs*18 | Frame Shift Ins (INS) | VAF 80/493 reads (16%) | catalogued as rs754902711; called by mutect2, varscan2
- IL17C | c.146dup p.H50Tfs*68 | Frame Shift Ins (INS) | VAF 48/248 reads (19%) | catalogued as rs773521874; called by mutect2, varscan2
- IL4R | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201209601; called by muse, mutect2, varscan2
- INCENP | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs576585430, COSV53916761; called by muse, mutect2, varscan2
- IPO4 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs754574474, COSV55778933, COSV55779068; called by muse, mutect2, varscan2
- IQCC | c.800del p.N267Tfs*51 | Frame Shift Del (DEL) | VAF 37/182 reads (20%) | catalogued as rs1400738656; called by mutect2, pindel, varscan2
- IRX3 | c.507G>A p.M169I | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV61668586; called by muse, varscan2
- IRX4 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 5/7 reads (71%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs909982802; called by mutect2, varscan2
- JAG2 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 141/595 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587724731; called by muse, mutect2, varscan2
- JAKMIP1 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs770405421, COSV51532368; called by muse, mutect2, varscan2
- KANSL1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs752415137, COSV52269623; ClinVar: likely benign; called by muse, mutect2, varscan2
- KBTBD6 | c.615C>A p.H205Q | Missense Mutation (SNP) | VAF 172/587 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs755218874, COSV101068810; called by muse, mutect2, varscan2
- KBTBD6 | c.614A>G p.H205R | Missense Mutation (SNP) | VAF 172/585 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765744005; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 51/244 reads (21%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNH1 | c.2387C>T p.T796M (on ENST00000271751 / NM_172362.3; = p.T769M on NM_002238.4) | Missense Mutation (SNP) | VAF 82/569 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs770040641, COSV55074553; called by muse, mutect2, varscan2
- KCNH3 | c.1584C>A p.H528Q | Missense Mutation (SNP) | VAF 86/345 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV99234880; called by muse, mutect2, varscan2
- KCNH6 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 99/418 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1408069335, COSV59005214; called by muse, mutect2, varscan2
- KCNJ6 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.25); catalogued as COSV55711957; called by muse, mutect2, varscan2
- KCNN1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1196737994; called by muse, mutect2, varscan2
- KCTD17 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.001); catalogued as COSV100696242; called by muse, mutect2, varscan2
- KCTD8 | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63598325; called by muse, mutect2, varscan2
- KIDINS220 | c.3242del p.P1081Rfs*48 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as COSV56750269; called by mutect2, pindel, varscan2
- KIF18B | c.1642del p.I548Lfs*8 (on ENST00000593135 / NM_001265577.2; = p.I560Lfs*8 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 122/547 reads (22%) | catalogued as COSV59271648; called by mutect2, varscan2
- KIF5C | c.2792A>G p.Y931C | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV68482137; called by muse, mutect2, varscan2
- LAMA1 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297300954, COSV67532144, COSV67538976; called by muse, mutect2
- LAMB2 | c.2479G>T p.G827C | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100026131; called by mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as COSV65473126, COSV65473260; called by mutect2, varscan2
- LILRB1 | c.1981del p.Q661Rfs*3 (on ENST00000427581; = p.Q610Rfs*3 on NM_006669.6) | Frame Shift Del (DEL) | VAF 89/344 reads (26%) | catalogued as rs748289578, COSV61117641; called by mutect2, pindel, varscan2
- LRP1B | c.7004C>G p.T2335S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1451393860; called by muse, mutect2, varscan2
- LSMEM2 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 75/338 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs587654943; called by muse, mutect2, varscan2
- MAP3K21 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1486052733, COSV64044637; called by muse, mutect2, varscan2
- MAP4K1 | c.2083G>A p.A695T | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.435); catalogued as rs564776236; called by muse, mutect2, varscan2
- MARCHF4 | c.213del p.G72Vfs*87 | Frame Shift Del (DEL) | VAF 31/113 reads (27%) | catalogued as COSV56104816; called by mutect2, pindel, varscan2
- MATN2 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367650132; called by muse, mutect2, varscan2
- MCF2 | c.51G>A p.A17= | Splice Region (SNP) | VAF 39/163 reads (24%) | catalogued as rs746578549, COSV58488334; called by muse, mutect2, varscan2
- MCF2L | c.1747C>A p.P583T (on ENST00000375608; = p.P551T on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as COSV65050263; called by muse, mutect2, varscan2
- MCTP1 | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs765527734; called by muse, mutect2, varscan2
- MCTP2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs141719358; called by muse, mutect2, varscan2
- MDC1 | c.2669T>C p.L890S | Missense Mutation (SNP) | VAF 101/408 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1250207757; called by muse, mutect2, varscan2
- MECP2 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs61754440, CD116883, COSV57652685; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MEF2A | c.1490G>A p.R497Q (on ENST00000557942 / NM_001319206.2; = p.R491Q on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs770266173; called by muse, mutect2, varscan2
- METTL25 | c.1585dup p.I529Nfs*10 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | catalogued as rs749712995; called by mutect2, varscan2
- MFSD2B | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as rs1325101722; called by muse, mutect2, varscan2
- MFSD4A | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 103/642 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.076); catalogued as rs770289370; called by muse, mutect2, varscan2
- MGRN1 | c.142del p.H48Tfs*13 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV52148537; called by pindel, varscan2
- MIB1 | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs892342186, COSV55091715; called by muse, mutect2, varscan2
- MID1IP1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs751701861; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MN1 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV56558932; called by muse, mutect2, varscan2
- MNDA | c.310del p.I104* | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | catalogued as rs751496931; called by mutect2, pindel, varscan2
- MRAS | c.256del p.D86Mfs*36 | Frame Shift Del (DEL) | VAF 31/169 reads (18%) | catalogued as COSV56673700; called by pindel, varscan2
- MRGPRX4 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV100049679, COSV58589877; called by muse, mutect2, varscan2
- MTSS1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs372826786; called by muse, mutect2, varscan2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1563799887; called by mutect2, pindel, varscan2
- MUC13 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs373312041, COSV60700053; called by muse, mutect2, varscan2
- MUC16 | c.21725C>A p.S7242Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV67458459, COSV67472760; called by muse, mutect2, varscan2
- MUC5B | c.6005C>T p.T2002M | Missense Mutation (SNP) | VAF 34/623 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs781521543; called by muse, mutect2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYBPH | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as rs772827472; called by muse, mutect2, varscan2
- MYCBP2 | c.2371C>T p.L791F (on ENST00000357337; = p.L829F on NM_015057.5) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62014693; called by muse, mutect2, varscan2
- MYH11 | c.2429A>G p.Q810R | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.928); catalogued as rs1202010177, COSV55553707; called by muse, mutect2, varscan2
- MYL2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.463); catalogued as rs942467544, CM1412318, COSV57407607; called by muse, varscan2
- MYO1H | c.2734del p.R912Gfs*24 | Frame Shift Del (DEL) | VAF 34/176 reads (19%) | catalogued as COSV60443785; called by mutect2, pindel, varscan2
- MYO7B | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs375619994; called by muse, mutect2, varscan2
- MZT2B | c.440del p.G147Afs*? | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | catalogued as rs772879277; called by mutect2, pindel, varscan2
- NAT8L | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV59051741; called by muse, mutect2, varscan2
- NCOA2 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV71763712; called by muse, mutect2, varscan2
- NCOA7 | c.311_313del p.K104del | In Frame Del (DEL) | VAF 12/90 reads (13%) | catalogued as rs986225466; called by pindel, varscan2
- NCOR2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as rs779023919; called by muse, mutect2, varscan2
- NDOR1 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 98/375 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs746275301; called by muse, mutect2, varscan2
- NELFB | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs539285051, COSV58025528; called by muse, varscan2
- NELL1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs143012314; called by muse, mutect2, varscan2
- NFASC | c.2489G>A p.R830H (on ENST00000339876 / NM_001378329.1; = p.R933H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs762878608, COSV100366059; called by muse, mutect2, varscan2
- NLRP11 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV64085706; called by muse, mutect2, varscan2
- NNT | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376701705; called by muse, mutect2, varscan2
- NOC4L | c.612del p.A205Pfs*13 | Frame Shift Del (DEL) | VAF 98/364 reads (27%) | catalogued as rs1402340327; called by mutect2, pindel, varscan2
- NOD2 | c.3098G>A p.C1033Y | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56048493; called by muse, mutect2, varscan2
- NOL7 | c.714del p.K238Nfs*16 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs544905440; called by mutect2, varscan2
- NOL8 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as rs373571114; called by muse, mutect2, varscan2
- NOTCH1 | c.4372G>A p.A1458T | Missense Mutation (SNP) | VAF 85/321 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs200495793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.3733G>A p.V1245M | Missense Mutation (SNP) | VAF 234/896 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs926643780, COSV53082744, COSV99486499; called by muse, mutect2, varscan2
- NR2E3 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 131/432 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs376858072; called by muse, mutect2, varscan2
- NR4A2 | c.383del p.P128Rfs*35 | Frame Shift Del (DEL) | VAF 71/279 reads (25%) | catalogued as COSV59894059, COSV99045223; called by mutect2, pindel, varscan2
- NRCAM | c.1464-1G>T p.X488_splice (on ENST00000379028 / NM_001371124.1; = p.X482_splice on NM_005010.4 and 21 other RefSeq transcripts) | Splice Site (SNP) | VAF 16/55 reads (29%) | catalogued as COSV61033594; called by muse, mutect2, varscan2
- NUP93 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369078681; called by muse, mutect2, varscan2
- NUTM2G | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 107/612 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as rs778682136; called by muse, mutect2, varscan2
- NYX | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as rs375834225; called by muse, mutect2, varscan2
- OFD1 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs1283023888, COSV60795916; called by mutect2, varscan2
- OGDHL | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs774306809, COSV65105065; called by muse, mutect2, varscan2
- OPCML | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1320560099, COSV59435895; called by muse, mutect2, varscan2
- OR10H5 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 91/399 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775742889; called by muse, mutect2, varscan2
- OR1B1 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 62/268 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs774435332, COSV59171232; called by muse, mutect2
- OR5D18 | c.423_424del p.C142Rfs*39 | Frame Shift Del (DEL) | VAF 47/425 reads (11%) | catalogued as rs760825221; called by pindel, varscan2
- OR6B2 | c.808T>G p.S270A | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.355); catalogued as COSV53156991; called by muse, mutect2, varscan2
- OR6N1 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV58647894; called by muse, mutect2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 24/115 reads (21%) | catalogued as rs201077183; called by mutect2, varscan2
- OR7C2 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 68/298 reads (23%) | catalogued as rs747041500; called by mutect2, varscan2
- OSBPL2 | c.590A>G p.H197R (on ENST00000313733 / NM_144498.4; = p.H185R on NM_014835.4) | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569130; called by muse, mutect2, varscan2
- OTOR | c.363G>A p.T121= | Splice Region (SNP) | VAF 15/80 reads (19%) | catalogued as rs1268273998; called by muse, mutect2, varscan2
- P2RX2 | c.283G>A p.V95M (on ENST00000343948 / NM_170683.4; = p.R72H on NM_012226.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs368657470, COSV100267791; called by muse, mutect2, varscan2
- P2RX6 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs746528036; called by muse, mutect2, varscan2
- PAQR6 | c.651G>T p.E217D (on ENST00000292291 / NM_001272108.2; = p.E111D on NM_024897.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/365 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99431803; called by muse, mutect2, varscan2
- PARD3 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs372172664; called by muse, mutect2, varscan2
- PARP4 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs758906539, COSV67962317; called by muse, mutect2, varscan2
- PAX3 | c.879del p.F294Sfs*87 | Frame Shift Del (DEL) | VAF 56/280 reads (20%) | catalogued as CD102010; called by mutect2, pindel, varscan2
- PCDH17 | c.3074T>C p.L1025P | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1198267761; called by muse, mutect2, varscan2
- PCDHA12 | c.1716C>A p.S572R | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs1554169431, COSV56528377; called by muse, varscan2
- PCDHB10 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.215); catalogued as rs782338014; called by muse, mutect2, varscan2
- PCDHB2 | c.223del p.M75Cfs*14 | Frame Shift Del (DEL) | VAF 44/162 reads (27%) | catalogued as rs782086614; called by mutect2, varscan2
- PCDHB6 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 195/670 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV50697153; called by muse, mutect2, varscan2
- PCDHGA1 | c.653del p.G218Vfs*32 | Frame Shift Del (DEL) | VAF 55/287 reads (19%) | catalogued as COSV65297564; called by mutect2, pindel, varscan2
- PCSK2 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs201712596, COSV99361069; called by muse, mutect2, varscan2
- PFKFB1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | catalogued as rs781298920, COSV100895553, COSV66628063; called by muse, mutect2, varscan2
- PFN3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.312); catalogued as rs1171801964; called by mutect2, varscan2
- PGBD5 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs569242579; called by muse, mutect2, varscan2
- PGGHG | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 79/391 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1000383447, COSV66888359; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 56/224 reads (25%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PI4KA | c.5116+1G>A p.X1706_splice | Splice Site (SNP) | VAF 74/265 reads (28%) | catalogued as rs773697738; called by muse, mutect2, varscan2
- PICK1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs756571367; called by muse, mutect2, varscan2
- PIGU | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs763023119, COSV99466649; called by muse, varscan2
- PIP5K1C | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1457887006, COSV58950265; called by muse, mutect2, varscan2
- PITX1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs140746945; called by muse, mutect2, varscan2
- PKD2 | c.2419C>T p.R807* | Nonsense Mutation (SNP) | VAF 96/359 reads (27%) | catalogued as CM971202, COSV52937953; called by muse, mutect2, varscan2
- PKLR | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 300/634 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM091408; called by muse, mutect2, varscan2
- PLCB2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs376517913; called by muse, mutect2, varscan2
- PLEC | c.7739A>G p.H2580R (on ENST00000322810 / NM_201380.4; = p.H2470R on NM_000445.5) | Missense Mutation (SNP) | VAF 124/513 reads (24%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as COSV100518555; called by muse, mutect2, varscan2
- PLG | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs1382198611, COSV51981579; called by muse, mutect2, varscan2
- PLOD1 | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 70/276 reads (25%) | catalogued as COSV52140498; called by muse, mutect2, varscan2
- PNPLA6 | c.3344C>T p.T1115M (on ENST00000414982 / NM_001166111.2; = p.T1067M on NM_006702.5) | Missense Mutation (SNP) | VAF 188/734 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1202026658, COSV99653886; ClinVar: uncertain significance; called by muse, varscan2
- POLQ | c.4289T>A p.L1430* | Nonsense Mutation (SNP) | VAF 55/217 reads (25%) | catalogued as rs377402875; called by muse, mutect2, varscan2
- POLR2M | c.601A>G p.I201V | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as rs372856991; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 81/374 reads (22%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPL | c.1362del p.T455Qfs*37 | Frame Shift Del (DEL) | VAF 38/118 reads (32%) | catalogued as rs753902804; called by mutect2, varscan2
- PPM1B | c.1015A>G p.M339V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs761929900, COSV99175749; called by muse, mutect2
- PPP1R1A | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs924687257; called by muse, mutect2, varscan2
- PPP1R36 | c.924del p.A309Lfs*31 | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | catalogued as COSV53901642; called by mutect2, pindel, varscan2
- PPP1R9B | c.2352G>T p.E784D | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs1391592227; called by muse, mutect2, varscan2
- PPP2R5C | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1185284111; called by muse, varscan2
- PPRC1 | c.2819del p.P940Hfs*6 | Frame Shift Del (DEL) | VAF 52/232 reads (22%) | catalogued as rs768056539; called by mutect2, varscan2
- PRB2 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV101231358, COSV104430975; called by muse, mutect2, varscan2
- PRDM15 | c.2060C>T p.S687L | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.31); catalogued as rs577548381; called by muse, mutect2, varscan2
- PRSS38 | c.566del p.G189Dfs*2 | Frame Shift Del (DEL) | VAF 46/352 reads (13%) | catalogued as rs1558231559, COSV64542387; called by mutect2, pindel, varscan2
- PRX | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99397863; called by muse, mutect2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 47/179 reads (26%) | catalogued as rs146650273; called by pindel, varscan2
- PTGES2 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99476238, COSV99476433; called by muse, varscan2
- PTGFRN | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.036); catalogued as rs150341125, COSV67797729; called by muse, mutect2, varscan2
- PTPRG | c.4003G>A p.V1335I | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as rs1174651225, COSV55638927; called by muse, mutect2, varscan2
- PURB | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67480276; called by muse, mutect2, varscan2
- PYGO2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as rs767913763; called by mutect2, varscan2
- RABL6 | c.1557del p.W520Gfs*79 | Frame Shift Del (DEL) | VAF 88/300 reads (29%) | catalogued as rs755631481, COSV100272944; called by mutect2, varscan2
- RADIL | c.1286del p.G429Afs*6 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs768989877; called by mutect2, pindel, varscan2
- RALGAPA1 | c.2237C>T p.A746V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99354018; called by muse, mutect2, varscan2
- RANBP6 | c.553T>G p.L185V | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV52389226; called by muse, mutect2, varscan2
- RD3L | c.564A>G p.I188M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs1427406056; called by muse, mutect2, varscan2
- RET | c.2572A>G p.I858V | Missense Mutation (SNP) | VAF 257/928 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV100391774; called by mutect2, varscan2
- RIMS1 | c.4501G>A p.G1501S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1251804745, COSV53456914; called by muse, mutect2, varscan2
- RIMS2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as rs770480422; called by muse, mutect2, varscan2
- RIPK4 | c.913del p.E305Kfs*13 | Frame Shift Del (DEL) | VAF 37/174 reads (21%) | catalogued as rs774700781; called by mutect2, pindel, varscan2
- RNF111 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as rs758101206; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 68/142 reads (48%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL28 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as rs1569040889, COSV59804778; called by muse, mutect2, varscan2
- RPS6KA4 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99590497, COSV99590647; called by muse, mutect2, varscan2
- RRP12 | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs554015140; called by muse, mutect2, varscan2
- RSPH4A | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs372304999, COSV57634123; called by muse, mutect2, varscan2
- RTN4R | c.1378del p.L460Wfs*91 | Frame Shift Del (DEL) | VAF 71/333 reads (21%) | catalogued as rs1250787345; called by mutect2, pindel, varscan2
- RXFP1 | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351663425, COSV57047463, COSV57052819; called by muse, mutect2, varscan2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 82/158 reads (52%) | catalogued as rs749201569; called by mutect2, varscan2
- SASH3 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 78/271 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs773919719, COSV63555879; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 37/80 reads (46%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SCN11A | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776207910, COSV56574685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.2010G>T p.E670D | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV57677939; called by muse, mutect2, varscan2
- SCN3A | c.2815G>A p.V939M | Missense Mutation (SNP) | VAF 115/472 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51806443; called by muse, mutect2, varscan2
- SEC23IP | c.1271T>G p.V424G | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64833214; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMG1 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1216262417; called by muse, mutect2, varscan2
- SEPHS1 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100526011; called by muse, varscan2
- SEPTIN9 | c.206A>G p.K69R (on ENST00000427177 / NM_001113491.2; = p.K51R on NM_006640.4) | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1345875612; called by muse, mutect2, varscan2
- SERPINB10 | c.913A>G p.T305A | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1568252042; called by muse, mutect2
- SETD1A | c.2121dup p.G708Rfs*117 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | catalogued as rs754369980; called by mutect2, varscan2
- SH2B2 | c.1691del p.P564Hfs*127 | Frame Shift Del (DEL) | VAF 45/168 reads (27%) | catalogued as rs782145245; called by mutect2, pindel, varscan2
- SH2D3C | c.1345C>T p.P449S (on ENST00000314830 / NM_170600.3; = p.P292S on NM_005489.4) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777457171, COSV100137606; called by muse, mutect2, varscan2
- SH3BP2 | c.1103del p.P368Qfs*21 | Frame Shift Del (DEL) | VAF 57/303 reads (19%) | catalogued as COSV62554014; called by mutect2, pindel, varscan2
- SH3PXD2B | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 118/454 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775645752, COSV61128064; called by muse, mutect2, varscan2
- SHH | c.1001G>C p.S334T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.171); catalogued as COSV51919155; called by muse, mutect2
- SIAE | c.68-3del | Splice Region (DEL) | VAF 79/325 reads (24%) | catalogued as rs746169895; called by mutect2, pindel, varscan2
- SIGLEC6 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as COSV58433617, COSV58435481; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 24/142 reads (17%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC18A3 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 65/223 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV60334922; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 36/110 reads (33%) | catalogued as rs749849908; called by mutect2, varscan2
- SLC27A1 | c.1124C>T p.T375M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs1475577807, COSV53101714; called by muse, mutect2, varscan2
- SLC34A2 | c.1880G>A p.R627H | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); catalogued as rs974734046; called by muse, varscan2
- SLC7A3 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1372449309, COSV53229797; called by muse, mutect2, varscan2
- SLITRK3 | c.1793C>G p.T598R | Missense Mutation (SNP) | VAF 102/410 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs772285952, COSV53854069; called by muse, mutect2, varscan2
- SLX4 | c.5480del p.G1827Afs*56 | Frame Shift Del (DEL) | VAF 104/408 reads (25%) | catalogued as rs780024167; ClinVar: uncertain significance; called by mutect2, varscan2
- SMAD2 | c.1394G>A p.S465N | Missense Mutation (SNP) | VAF 159/309 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50992851, COSV50992877; called by muse, mutect2, varscan2
- SMG1 | c.2906A>G p.N969S | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1412788971, COSV67172829; called by muse, mutect2
- SMYD5 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as rs1026721037; called by muse, mutect2, varscan2
- SND1 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs755722783; called by muse, mutect2, varscan2
- SOHLH1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 134/615 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437844943; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 10/39 reads (26%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SORL1 | c.5285A>T p.Y1762F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1367197725; called by muse, mutect2, varscan2
- SOS2 | c.2784del p.F928Lfs*5 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | catalogued as rs1347298671; called by mutect2, pindel, varscan2
- SOWAHD | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs777575814; called by muse, mutect2, varscan2
- SPATA2L | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as rs772736744; called by muse, mutect2, varscan2
- SPATA31D1 | c.574G>C p.A192P | Missense Mutation (SNP) | VAF 134/491 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781026076, COSV61203270; called by mutect2, varscan2
- SPEG | c.9728G>A p.G3243D | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs1162289173; called by muse, mutect2
- SPEN | c.2530C>T p.R844* | Nonsense Mutation (SNP) | VAF 41/157 reads (26%) | catalogued as COSV65358929; called by muse, mutect2, varscan2
- SPNS2 | c.1347C>T p.Y449= | Splice Region (SNP) | VAF 63/218 reads (29%) | catalogued as rs1020563491, COSV54593871, COSV54601268; called by muse, mutect2, varscan2
- SPTA1 | c.3352A>G p.K1118E | Missense Mutation (SNP) | VAF 41/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs994266055, COSV63749450; called by muse, mutect2, varscan2
- SREBF1 | c.3139G>A p.G1047R | Missense Mutation (SNP) | VAF 178/651 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.463); catalogued as rs762911298, COSV99883297; called by muse, mutect2, varscan2
- SRGAP2 | c.1036C>T p.P346S (on ENST00000624873 / NM_001170637.4; = p.P347S on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/337 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.081); catalogued as rs781918979; called by muse, mutect2, varscan2
- SSC4D | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV51883718; called by muse, mutect2, varscan2
- SSC5D | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1451618613, COSV67476336; called by muse, mutect2, varscan2
- STAB1 | c.3793G>A p.A1265T | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1181556012; called by muse, mutect2, varscan2
- STEAP2 | c.680del p.F227Sfs*9 | Frame Shift Del (DEL) | VAF 40/149 reads (27%) | catalogued as rs754344704; called by mutect2, varscan2
- STXBP5L | c.2872G>A p.A958T | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV56523892; called by muse, mutect2, varscan2
- SUPT5H | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs767152685; called by muse, mutect2, varscan2
- SYCP1 | c.1221A>G p.I407M | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs772010689; called by muse, mutect2, varscan2
- SYK | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65328217; called by muse, mutect2, varscan2
- TARDBP | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs1358405889, COSV53570753; called by muse, mutect2, varscan2
- TARS2 | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs139360997; called by muse, mutect2, varscan2
- TBC1D10C | c.960del p.A321Rfs*100 | Frame Shift Del (DEL) | VAF 17/81 reads (21%) | catalogued as rs751687887; called by mutect2, pindel, varscan2
- TBC1D2 | c.2549G>A p.R850H (on ENST00000465784 / NM_001267571.2; = p.R839H on NM_018421.4) | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs775339179; called by muse, mutect2, varscan2
- TCTN2 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.192); catalogued as rs886049055; called by muse, mutect2, varscan2
- TDRD15 | c.4698del p.K1566Nfs*14 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs750572471; called by mutect2, varscan2
- TECPR2 | c.3199A>G p.M1067V | Missense Mutation (SNP) | VAF 87/300 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs150410856; called by muse, mutect2, varscan2
- TICAM1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1444390257; called by muse, mutect2, varscan2
- TLE4 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 63/285 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779285596, COSV99512556; called by muse, mutect2, varscan2
- TLN2 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs763045450, COSV100168719; called by muse, mutect2, varscan2
- TLR9 | c.206C>A p.S69Y | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as COSV100564607; called by muse, mutect2, varscan2
- TMC3 | c.3302A>G p.*1101Wext*30 | Nonstop Mutation (SNP) | VAF 11/94 reads (12%) | catalogued as rs951950405; called by muse, mutect2, varscan2
- TMEM132E | c.1643G>A p.R548Q (on ENST00000321639; = p.R638Q on NM_001304438.2) | Missense Mutation (SNP) | VAF 89/390 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs752049579, COSV58695983, COSV58696791; called by muse, mutect2, varscan2
- TMEM255A | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs781913217; called by muse, mutect2, varscan2
- TNFRSF11A | c.1144del p.E382Rfs*5 | Frame Shift Del (DEL) | VAF 86/371 reads (23%) | catalogued as COSV54022187, COSV99500361; called by mutect2, pindel, varscan2
- TNRC18 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV101259336; called by muse, mutect2, varscan2
- TNRC6A | c.4870A>G p.I1624V | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs764858647; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 27/105 reads (26%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TOPAZ1 | c.1893del p.A632Lfs*5 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | catalogued as rs753884819, COSV59073348; called by mutect2, varscan2
- TOX4 | c.294del p.L99Sfs*2 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | catalogued as COSV52967384; called by mutect2, pindel, varscan2
- TP63 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV53211567; called by muse, mutect2
- TPTE | c.1235G>A p.R412Q (on ENST00000618007 / NM_199261.4; = p.R394Q on NM_199259.4) | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs756871735; called by muse, mutect2
- TRAPPC2L | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV51938432; called by muse, mutect2, varscan2
- TRHDE | c.2732C>A p.S911Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99668353; called by muse, mutect2
- TRIM37 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1264456708; called by muse, mutect2, varscan2
- TRIOBP | c.4436dup p.T1480Hfs*22 | Frame Shift Ins (INS) | VAF 73/310 reads (24%) | catalogued as rs756145453; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 16/75 reads (21%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.100795C>T p.R33599W (on ENST00000591111; = p.R26175W on NM_003319.4) | Missense Mutation (SNP) | VAF 73/276 reads (26%) | PolyPhen possibly damaging (0.528); catalogued as rs752729073, COSV59864573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs760251146; called by mutect2, varscan2
- TXNDC8 | c.241A>G p.K81E | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1315678774; called by muse, mutect2, varscan2
- UBP1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.968); catalogued as COSV52144862; called by muse, mutect2, varscan2
- UBXN6 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.945); catalogued as rs369398559; called by muse, mutect2, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 143/619 reads (23%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- ULK4 | c.1910C>A p.S637Y | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57208289; called by muse, mutect2, varscan2
- UNC79 | c.4478del p.K1493Sfs*12 (on ENST00000393151 / NM_001346218.2; = p.K1316Sfs*12 on NM_020818.5) | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | catalogued as rs760213136; called by mutect2, varscan2
- USP28 | c.2687G>A p.R896Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770592432, COSV50186010; called by mutect2, varscan2
- USP30 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as rs781764916; called by muse, mutect2, varscan2
- USP36 | c.325C>T p.R109* | Nonsense Mutation (SNP) | VAF 100/398 reads (25%) | catalogued as COSV61752633; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs761528888; called by mutect2, varscan2
- VEPH1 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 48/180 reads (27%) | catalogued as rs200324023; called by muse, mutect2, varscan2
- VIT | c.1448G>A p.R483H (on ENST00000389975 / NM_001177969.1; = p.R498H on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1318456793; called by muse, mutect2, varscan2
- VPS33A | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs200143325, COSV57355926; called by muse, mutect2, varscan2
- VPS33A | c.251G>A p.R84K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57355809; called by muse, mutect2, varscan2
- VSIG1 | c.1028A>T p.D343V | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs375367987; called by muse, mutect2, varscan2
- VWA5A | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | catalogued as COSV63708277; called by muse, mutect2, varscan2
- VWA7 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1384156757, COSV100791819; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR61 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV51216953; called by muse, mutect2, varscan2
- XIRP1 | c.3402del p.W1135Gfs*2 | Frame Shift Del (DEL) | VAF 56/273 reads (21%) | catalogued as rs1166941994; called by mutect2, varscan2
- XKR5 | c.2054del p.F685Sfs*49 | Frame Shift Del (DEL) | VAF 21/86 reads (24%) | catalogued as rs1397775802; called by mutect2, pindel, varscan2
- ZC3H18 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.552); catalogued as rs368961958; called by muse, mutect2, varscan2
- ZC3H3 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 17/578 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs770790299, COSV52794894; called by muse, mutect2
- ZCCHC14 | c.1894G>A p.A632T (on ENST00000268616; = p.A769T on NM_015144.3) | Missense Mutation (SNP) | VAF 126/463 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1285027012, COSV51887754; called by muse, mutect2, varscan2
- ZIC3 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs772291510; called by muse, mutect2, varscan2
- ZIC4 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs775064886; called by muse, mutect2
- ZMIZ1 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as rs1375006069; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 40/152 reads (26%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF121 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 82/324 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1259879455; called by muse, mutect2, varscan2
- ZNF140 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs767417735; called by muse, mutect2, varscan2
- ZNF229 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 109/478 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as rs946497405; called by muse, mutect2, varscan2
- ZNF267 | c.1469A>G p.K490R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs1472087916; called by muse, mutect2, varscan2
- ZNF423 | c.2003G>A p.R668Q (on ENST00000563137 / NM_001379286.1; = p.R660Q on NM_015069.4) | Missense Mutation (SNP) | VAF 87/375 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.205); catalogued as rs200218868, COSV52202105, COSV99283618; called by muse, mutect2, varscan2
- ZNF423 | c.572G>A p.R191Q (on ENST00000563137 / NM_001379286.1; = p.R183Q on NM_015069.4) | Missense Mutation (SNP) | VAF 129/480 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1473298259, COSV52194192; called by muse, mutect2, varscan2
- ZNF446 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs759571274; called by muse, mutect2, varscan2
- ZNF469 | c.11430del p.S3811Qfs*102 (on ENST00000437464; = p.S3839Qfs*102 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 62/294 reads (21%) | catalogued as rs1195589065; called by mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 27/144 reads (19%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF558 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.854); catalogued as rs1020176374, COSV56863707; called by muse, mutect2
- ZNF668 | c.1543del p.Q515Sfs*14 | Frame Shift Del (DEL) | VAF 34/156 reads (22%) | catalogued as rs760397907; called by mutect2, varscan2
- ZNF668 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs1472661496, COSV100336774; called by muse, mutect2, varscan2
- ZNF687 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 67/377 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55017674; called by muse, mutect2, varscan2
- ZNF738 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs758757360; called by muse, mutect2, varscan2
- ZNF860 | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.069); catalogued as rs776070083, COSV64384577; called by muse, mutect2, varscan2
- A2M | c.2260G>A p.V754I | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ABCB6 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABCC11 | c.4142T>A p.L1381Q | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ABCC12 | c.1262dup p.S422Ifs*25 | Frame Shift Ins (INS) | VAF 39/203 reads (19%) | called by mutect2, pindel, varscan2
- ABLIM1 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ACBD7 | c.192dup p.G65Rfs*14 | Frame Shift Ins (INS) | VAF 28/132 reads (21%) | called by mutect2, pindel, varscan2
- ACE | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 160/617 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACOXL | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ACSL4 | c.2087T>C p.L696P (on ENST00000340800 / NM_022977.2; = p.L655P on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACTR1A | c.10T>A p.Y4N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ADARB2 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD3 | c.1240del p.S414Pfs*27 | Frame Shift Del (DEL) | VAF 60/212 reads (28%) | called by mutect2, varscan2
- ADGRV1 | c.893A>C p.E298A | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- AGAP2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AGAP4 | c.737del p.P246Rfs*22 | Frame Shift Del (DEL) | VAF 71/505 reads (14%) | called by mutect2, pindel, varscan2
- AGXT | c.595+5G>T | Splice Region (SNP) | VAF 44/150 reads (29%) | called by muse, mutect2, varscan2
- AHDC1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AIM2 | c.1006-11_1018delinsCTCCCTCCAGGTTATTAAGGCC p.X336_splice | Splice Site (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2*
- AKNAD1 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2
- ALAS2 | c.1476_1478del p.L494del | In Frame Del (DEL) | VAF 51/234 reads (22%) | called by pindel, varscan2
- ALG12 | c.454C>A p.L152M | Missense Mutation (SNP) | VAF 130/517 reads (25%) | PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AMIGO3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 78/295 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- ANGPT2 | c.930+2T>C p.X310_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ANKRD6 | c.838_839dup p.L281Gfs*125 | Frame Shift Ins (INS) | VAF 56/263 reads (21%) | called by mutect2, varscan2
- ANKS1B | c.1681G>T p.A561S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AOX1 | c.2124+2T>C p.X708_splice | Splice Site (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- APC2 | c.6754G>A p.A2252T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP20 | c.803T>C p.M268T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARHGAP24 | c.577G>A p.G193R (on ENST00000395184 / NM_001025616.3; = p.G100R on NM_031305.3) | Missense Mutation (SNP) | VAF 61/262 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ARHGEF1 | c.2572G>T p.G858W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ARHGEF11 | c.2523_2533del p.E841Dfs*17 | Frame Shift Del (DEL) | VAF 97/258 reads (38%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.151T>C p.F51L | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by mutect2, varscan2
- ARHGEF40 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ARRB1 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ARSD | c.637A>G p.T213A | Missense Mutation (SNP) | VAF 88/388 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ASH1L | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 162/314 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ASIC3 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- ATG4A | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ATN1 | c.2622del p.Y875Tfs*78 | Frame Shift Del (DEL) | VAF 85/328 reads (26%) | called by mutect2, varscan2
- ATP1A2 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 72/457 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP2B4 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP5MPL | c.4C>T p.L2F | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATP6V0A2 | c.119T>A p.L40H | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ATP8B2 | c.1051A>G p.S351G (on ENST00000672630; = p.S318G on NM_001005855.2) | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ATRX | c.7025T>G p.V2342G | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ATRX | c.7024G>A p.V2342M | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ATXN7 | c.2333del p.G778Afs*14 | Frame Shift Del (DEL) | VAF 37/349 reads (11%) | called by mutect2, pindel, varscan2
- BCR | c.667G>T p.V223L | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRCC3 | c.923T>C p.L308P | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BRPF3 | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 112/431 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSDC1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- C20orf203 | c.316dup p.E106Gfs*15 | Frame Shift Ins (INS) | VAF 22/121 reads (18%) | called by pindel, varscan2
- C4orf17 | c.651G>T p.L217F | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CACNA2D1 | c.1759del p.T587Hfs*45 (on ENST00000356253 / NM_001366867.1; = p.T568Hfs*45 on NM_000722.4) | Frame Shift Del (DEL) | VAF 17/88 reads (19%) | called by mutect2, pindel, varscan2
- CACNA2D2 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 103/498 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAND1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAPN6 | c.1044del p.F348Lfs*20 | Frame Shift Del (DEL) | VAF 48/194 reads (25%) | called by mutect2, pindel, varscan2
- CASP1 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 55/265 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCDC137 | c.495dup p.A166Sfs*9 | Frame Shift Ins (INS) | VAF 38/183 reads (21%) | called by mutect2, varscan2
- CCDC141 | c.1077del p.F359Lfs*26 | Frame Shift Del (DEL) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- CCDC18 | c.697A>G p.R233G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC47 | c.1312del p.R438Efs*8 | Frame Shift Del (DEL) | VAF 55/194 reads (28%) | called by mutect2, pindel, varscan2
- CCDC88A | c.575del p.N192Ifs*6 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- CCDC88B | c.63G>A p.A21= | Splice Region (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- CCNB1IP1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.422); called by muse, mutect2
- CDC42BPG | c.4226G>A p.R1409H | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC5L | c.829T>C p.S277P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH1 | c.1033G>T p.V345F | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CDHR1 | c.1096T>C p.S366P | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CDK13 | c.2750A>T p.N917I | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDK15 | c.803dup p.D269* (on ENST00000652192 / NM_001366386.2; = p.D218* on NM_139158.2) | Frame Shift Ins (INS) | VAF 19/98 reads (19%) | called by mutect2, pindel, varscan2
- CDK5R2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- CDK8 | c.138T>A p.D46E | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPE | c.6721-2A>C p.X2241_splice | Splice Site (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- CEP162 | c.2761del p.I921Ffs*15 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, pindel, varscan2
- CEP170 | c.611del p.N204Tfs*11 | Frame Shift Del (DEL) | VAF 56/128 reads (44%) | called by mutect2, pindel, varscan2
- CEP170B | c.1964del p.G655Afs*169 (on ENST00000453495; = p.G584Afs*169 on NM_015005.3) | Frame Shift Del (DEL) | VAF 48/181 reads (27%) | called by mutect2, pindel, varscan2
- CEP295 | c.4800A>C p.Q1600H | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CEP95 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CFAP46 | c.4089del p.E1364Rfs*56 | Frame Shift Del (DEL) | VAF 82/398 reads (21%) | called by mutect2, pindel, varscan2
- CFH | c.2720T>C p.I907T | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- CHRNB3 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIAO3 | c.436del p.I146* | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, varscan2
- CKAP4 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 104/398 reads (26%) | called by mutect2, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | called by mutect2, varscan2
- CLCN4 | c.1931G>A p.R644H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CLDN4 | c.537del p.L180Cfs*115 | Frame Shift Del (DEL) | VAF 58/250 reads (23%) | called by mutect2, varscan2
- CLDN6 | c.567del p.S190Pfs*70 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, varscan2
- CNDP2 | c.1010T>C p.V337A | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2
- CNPY2 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 70/368 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CNTN3 | c.1387G>T p.G463* | Nonsense Mutation (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- COBL | c.499dup p.A167Gfs*8 | Frame Shift Ins (INS) | VAF 51/274 reads (19%) | called by mutect2, pindel, varscan2
- COL12A1 | c.3135del p.T1046Qfs*7 | Frame Shift Del (DEL) | VAF 42/196 reads (21%) | called by mutect2, varscan2
- COL5A2 | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CSE1L | c.2597C>A p.T866N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CSMD3 | c.7149del p.F2383Lfs*10 (on ENST00000297405 / NM_001363185.1; = p.F2279Lfs*10 on NM_052900.3) | Frame Shift Del (DEL) | VAF 41/241 reads (17%) | called by mutect2, pindel, varscan2
- CSNK2A1 | c.4_15del p.S2_V5del | In Frame Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- CYP11B1 | c.527T>C p.V176A | Missense Mutation (SNP) | VAF 26/690 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.318); called by muse, mutect2
- CYP4F2 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAAM1 | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DAG1 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 210/808 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAP3 | c.381T>C p.Y127= | Splice Region (SNP) | VAF 71/131 reads (54%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.152A>G p.Y51C | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCUN1D5 | c.610A>G p.S204G | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DENND1A | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- DENND1C | c.848A>C p.E283A | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- DENND4A | c.5548G>T p.G1850W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DERPC | c.104del p.G35Vfs*4 | Frame Shift Del (DEL) | VAF 65/330 reads (20%) | called by mutect2, pindel, varscan2
- DISP1 | c.2800A>G p.T934A | Missense Mutation (SNP) | VAF 95/731 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DLL3 | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- DMRTA2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH2 | c.2929T>C p.Y977H | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNAH8 | c.1952A>G p.D651G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- DNAJC13 | c.727del p.I243Yfs*13 | Frame Shift Del (DEL) | VAF 12/123 reads (10%) | called by mutect2, pindel
- DNASE1L2 | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK9 | c.4002del p.F1334Lfs*19 (on ENST00000376460 / NM_001366676.2; = p.F1335Lfs*19 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by mutect2, pindel, varscan2
- DOCK9 | c.776T>A p.L259H (on ENST00000376460 / NM_001366676.2; = p.L260H on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- DSC2 | c.2495C>A p.P832H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DST | c.7909_7910del p.S2637* | Frame Shift Del (DEL) | VAF 66/301 reads (22%) | called by mutect2, pindel, varscan2
- DST | c.6803G>A p.G2268D | Missense Mutation (SNP) | VAF 91/385 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DUSP29 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUXB | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DVL2 | c.2101del p.A701Pfs*14 | Frame Shift Del (DEL) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.5705del p.G1902Vfs*27 | Frame Shift Del (DEL) | VAF 58/256 reads (23%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.8213A>G p.Y2738C | Missense Mutation (SNP) | VAF 16/542 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DYNC2H1 | c.8311+1_8311+8del p.X2771_splice | Splice Site (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- E2F1 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- EFCAB6 | c.4233+1G>A p.X1411_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2
- EFNA5 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- EIPR1 | c.293T>G p.V98G | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); called by muse, mutect2
- ENTPD2 | c.700del p.R234Efs*141 | Frame Shift Del (DEL) | VAF 87/363 reads (24%) | called by mutect2, pindel, varscan2
- EPAS1 | c.2462-2A>G p.X821_splice | Splice Site (SNP) | VAF 145/582 reads (25%) | called by muse, mutect2, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 88/376 reads (23%) | called by mutect2, varscan2
- EPPK1 | c.3886C>T p.Q1296* | Nonsense Mutation (SNP) | VAF 58/236 reads (25%) | called by muse, mutect2, varscan2
- EPX | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 182/733 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ERICH3 | c.1490-1G>A p.X497_splice | Splice Site (SNP) | VAF 29/177 reads (16%) | called by muse, mutect2, varscan2
- ERMAP | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 71/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ERV3-1 | c.1189T>C p.S397P | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ESYT2 | c.1066T>C p.S356P (on ENST00000613624; = p.S280P on NM_020728.3) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ETFDH | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- EXO1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 51/301 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- EXOSC8 | c.485del p.N162Mfs*9 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | called by mutect2, pindel, varscan2
- EYS | c.9034del p.T3012Qfs*4 (on ENST00000370621 / NM_001292009.1; = p.T2991Qfs*4 on NM_001142800.2) | Frame Shift Del (DEL) | VAF 80/375 reads (21%) | called by mutect2, pindel, varscan2
- EYS | c.4250T>C p.V1417A | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- FAM114A2 | c.630+2T>C p.X210_splice | Splice Site (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- FAM162A | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.277); called by muse, varscan2
- FAM186B | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM83H | c.2804G>A p.G935D | Missense Mutation (SNP) | VAF 132/398 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT2 | c.9008A>G p.D3003G | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.6237C>G p.D2079E | Missense Mutation (SNP) | VAF 90/388 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBP2 | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- FCRL5 | c.1172T>C p.I391T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FLYWCH1 | c.1364A>C p.Q455P (on ENST00000253928 / NM_001308068.2; = p.Q454P on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GABRG3 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- GOLGA3 | c.3550_3552del p.E1184del | In Frame Del (DEL) | VAF 38/149 reads (26%) | called by mutect2, pindel, varscan2
- GON4L | c.6439A>G p.S2147G | Missense Mutation (SNP) | VAF 46/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GPAT4 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPAT4 | c.707del p.N236Tfs*19 | Frame Shift Del (DEL) | VAF 39/178 reads (22%) | called by mutect2, pindel, varscan2
- GPBAR1 | c.473A>G p.Q158R | Missense Mutation (SNP) | VAF 94/419 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR141 | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR150 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GPR162 | c.1759A>G p.T587A (on ENST00000311268 / NM_019858.2; = p.T303A on NM_014449.2) | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- GRIN2B | c.2984G>A p.G995D | Missense Mutation (SNP) | VAF 190/858 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- GRIN2B | c.2611T>C p.C871R | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSPT2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GXYLT2 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GYG2 | c.1447T>C p.Y483H | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- H2BC17 | c.255_257del p.N85del | In Frame Del (DEL) | VAF 33/197 reads (17%) | called by pindel, varscan2
- HCAR2 | c.500T>C p.M167T | Missense Mutation (SNP) | VAF 116/542 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.109); called by mutect2, varscan2
- HCFC1 | c.3691G>C p.G1231R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC5 | c.1767G>T p.E589D | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR5A | c.3057A>C p.Q1019H | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW2 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- HHIP | c.1977del p.G660Dfs*17 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | called by mutect2, varscan2
- HIF1A | c.896A>C p.Q299P | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HK1 | c.119T>C p.M40T | Missense Mutation (SNP) | VAF 54/618 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.006); called by muse, mutect2
- HLA-B | c.626del p.P209Qfs*5 | Frame Shift Del (DEL) | VAF 50/212 reads (24%) | called by pindel, varscan2
- HMBS | c.613-7T>C | Splice Region (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- HMGA1 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HNRNPA1 | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HS3ST3B1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- HS3ST4 | c.553G>A p.G185S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPA14 | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ICAM5 | c.2192A>G p.H731R | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ICE1 | c.6521-1G>A p.X2174_splice | Splice Site (SNP) | VAF 24/117 reads (21%) | called by muse, mutect2, varscan2
- IFIT2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 109/448 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- IFT88 | c.2182del p.M728* (on ENST00000319980 / NM_001318493.2; = p.M719* on NM_006531.5 and 9 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 170/672 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IL1RAPL1 | c.1288G>T p.A430S | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IMP3 | c.336dup p.T113Hfs*29 | Frame Shift Ins (INS) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- INHBE | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS13 | c.958A>G p.T320A | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- IPO4 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, mutect2
- IPO4 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPO5 | c.171+2T>C p.X57_splice | Splice Site (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- IRAK4 | c.1030A>G p.M344V | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IRS4 | c.3526A>G p.R1176G | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ITGA8 | c.2381A>G p.H794R | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ITIH6 | c.1055A>G p.H352R | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN1 | c.3846del p.F1282Lfs*2 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | called by mutect2, pindel, varscan2
- JUP | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 121/484 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- KAT2B | c.363del p.R122Efs*7 | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- KAZN | c.112C>A p.L38I | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- KCNQ2 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KDM4B | c.2458T>C p.C820R | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5C | c.4510G>T p.G1504C | Missense Mutation (SNP) | VAF 89/355 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1522 | c.1954dup p.Q652Pfs*35 (on ENST00000373480 / NM_001198972.2; = p.Q711Pfs*35 on NM_020888.3) | Frame Shift Ins (INS) | VAF 20/94 reads (21%) | called by mutect2, pindel, varscan2
- KIF13A | c.956del p.G319Afs*7 | Frame Shift Del (DEL) | VAF 48/177 reads (27%) | called by mutect2, varscan2
- KIF14 | c.4673G>A p.S1558N | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF26B | c.5383C>A p.L1795M | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KIF2A | c.1305C>G p.S435R | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4A | c.2354del p.K785Rfs*39 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- KIF5A | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 97/414 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- KLHDC2 | c.1059A>T p.E353D | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KMT2B | c.481del p.L161Ffs*6 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- KMT2C | c.11165A>C p.K3722T | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 52/231 reads (23%) | called by mutect2, pindel, varscan2
- KRTAP10-10 | c.267del p.C90Afs*177 | Frame Shift Del (DEL) | VAF 82/387 reads (21%) | called by mutect2, pindel, varscan2
- KRTAP6-3 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 53/224 reads (24%) | PolyPhen probably damaging (1); called by mutect2, varscan2
- LARS1 | c.1774_1782del p.E592_L594del (on ENST00000394434 / NM_020117.11; = p.E565_L567del on NM_016460.3) | In Frame Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- LDLRAD2 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LHCGR | c.182T>A p.V61D | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- LRP4 | c.570del p.C191Afs*206 | Frame Shift Del (DEL) | VAF 54/201 reads (27%) | called by mutect2, pindel, varscan2
- LRP5 | c.2468T>C p.L823P | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC56 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 79/320 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LSM12 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LTBP2 | c.1864+2T>C p.X622_splice | Splice Site (SNP) | VAF 20/528 reads (4%) | called by muse, mutect2
- LTF | c.1756A>T p.K586* | Nonsense Mutation (SNP) | VAF 46/218 reads (21%) | called by muse, mutect2, varscan2
- MAGEB1 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 69/318 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MAGEE1 | c.2109G>A p.W703* | Nonsense Mutation (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- MAGI3 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2
- MAML2 | c.2349A>C p.K783N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MANBA | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K11 | c.2431C>T p.P811S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAP3K9 | c.2680C>T p.Q894* (on ENST00000554752 / NM_001284230.1; = p.Q908* on NM_033141.4) | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.3406G>T p.G1136C | Missense Mutation (SNP) | VAF 64/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAU2 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- MBD2 | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | called by mutect2, varscan2
- MECOM | c.314del p.K105Sfs*13 | Frame Shift Del (DEL) | VAF 56/222 reads (25%) | called by mutect2, pindel, varscan2
- MEGF10 | c.2453A>G p.Y818C | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEIS2 | c.187G>A p.A63T (on ENST00000561208 / NM_170675.5; = p.A50T on NM_002399.3) | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- MGST1 | c.64A>C p.I22L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MISP3 | c.926A>T p.E309V (on ENST00000269720; = p.E167V on NM_001291291.2) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2
- MLPH | c.782A>G p.Q261R | Missense Mutation (SNP) | VAF 28/536 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.346); called by muse, mutect2
- MMEL1 | c.536-1G>T p.X179_splice | Splice Site (SNP) | VAF 17/144 reads (12%) | called by muse, mutect2, varscan2
- MMP24 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MMRN1 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- MMUT | c.29del p.L10Yfs*7 | Frame Shift Del (DEL) | VAF 40/185 reads (22%) | called by mutect2, pindel, varscan2
- MOGAT2 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 117/517 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MRAP | c.488del p.P163Lfs*18 | Frame Shift Del (DEL) | VAF 101/420 reads (24%) | called by mutect2, pindel, varscan2
- MRM2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 113/433 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTRR | c.2051C>T p.A684V (on ENST00000264668; = p.A657V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTUS2 | c.1570G>A p.A524T | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC16 | c.23171G>A p.G7724D | Missense Mutation (SNP) | VAF 51/206 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC19 | n.5473A>T | Splice Region (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- MUC22 | c.5204T>G p.M1735R | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- MUC5B | c.11753T>C p.V3918A | Missense Mutation (SNP) | VAF 183/869 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUSK | c.1561A>T p.R521* | Nonsense Mutation (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- MXRA5 | c.938T>A p.L313Q | Missense Mutation (SNP) | VAF 73/273 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH11 | c.4097T>C p.I1366T | Missense Mutation (SNP) | VAF 132/522 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MYH15 | c.4529T>C p.L1510P | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- MYH7 | c.42del p.Y15Tfs*10 | Frame Shift Del (DEL) | VAF 94/515 reads (18%) | called by mutect2, pindel, varscan2
- MYH8 | c.5261C>T p.A1754V | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- MYO16 | c.4055A>T p.K1352M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- NAA16 | c.2452T>A p.S818T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAT8L | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- NAV3 | c.3152del p.K1051Sfs*23 | Frame Shift Del (DEL) | VAF 56/224 reads (25%) | called by mutect2, pindel, varscan2
- NAXE | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 72/466 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.278); called by muse, mutect2
- NBAS | c.2111T>C p.V704A | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NDOR1 | c.200del p.P67Lfs*4 | Frame Shift Del (DEL) | VAF 28/120 reads (23%) | called by mutect2, pindel, varscan2
- NDST3 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDUFA8 | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NFATC1 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFIX | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 92/409 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NGRN | c.79del p.V27Wfs*31 | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- NKAP | c.1176G>C p.K392N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKD1 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NKX2-6 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC5 | c.5266A>T p.T1756S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- NOTCH1 | c.7455del p.S2486Rfs*103 | Frame Shift Del (DEL) | VAF 52/237 reads (22%) | called by mutect2, pindel, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 57/197 reads (29%) | called by mutect2, varscan2
- NPIPB6 | c.882dup p.S295Lfs*4 | Frame Shift Ins (INS) | VAF 120/410 reads (29%) | called by mutect2, varscan2
717 further variants in this file (219 protein-altering or splice-affecting, 299 silent, 199 other) are not listed here.
